Gene-level copy-number profile of tumor specimen C3N-02681-02 from CPTAC case C3N-02681, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.7 years (23,981 days).
Specimen C3N-02681-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ff9d30dc-c6aa-41d4-9b52-6f575f6a173a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02681-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/82388b02-e1a9-4022-9b44-202e89b22369

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 3,082; copy number 2: 54,500; copy number 3: 648; copy number 4: 1; copy number 5: 2; copy number 6: 23; copy number 41: 6; copy number 42: 2; copy number 43: 2; copy number 45: 17; copy number 182: 1; copy number 197: 12.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,999,509–23,438,700, 60 genes: HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr9:25,676,389–25,844,585, 2 genes: TUSC1, LINC01241.
- chr9:27,102,630–28,888,955, 21 genes: AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873.
- chr10:47,689,707–48,119,455, 12 genes: SHLD2P3, RN7SL453P, RHEBP2, FO681492.1, AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 65 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:39,182,504–39,451,533, 7 genes, copy number 6: WDR19, RFC1, RNU6-32P, RNU6-887P, KLB, MIR5591, Y_RNA.
- chr7:54,542,325–55,260,256, 13 genes, copy number 182–197: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr8:66,112,667–66,667,231, 16 genes, copy number 6: AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA.
- chr12:64,507,001–64,697,564, 1 gene, copy number 45 (within-gene range 1–45): RASSF3.
- chr12:64,654,060–64,710,513, 3 genes, copy number 45: AC078962.3, AC025262.2, AC025262.1.
- chr12:68,746,125–69,274,358, 13 genes, copy number 45: SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279.
- chr12:69,359,710–69,401,200, 2 genes, copy number 5: YEATS4, RN7SL804P.
- chr12:69,713,633–69,823,204, 2 genes, copy number 42 (within-gene range 1–42): AC025263.1, RAB3IP.
- chr12:95,217,746–95,309,984, 6 genes, copy number 41: VEZT, Y_RNA, CBX3P5, RNU6-808P, MIR331, MIR3685.
- chr16:24,919,389–25,021,023, 2 genes, copy number 43: ARHGAP17, AC133552.1.

Autosomal genes at a single copy (total copy number 1): 3,082. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
